CCDI case PBBZGW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/a3be1cae-ccac-4351-a4c8-276ac41c1be0

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.9 years (314 days).

Biospecimens (3 samples)
- Sample 0DLFAZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLFBI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLFBS: Tissue type: Tumor; Specimen type: Solid Tissue.
